Surgical pathology report (de-identified scan), TCGA case TCGA-E1-A7YS, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-A7YS-01A (Primary Tumor).

[page 1 of 3]
Patient: [REDACTED]

Surgical Pathology: Additional Info [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

Brain neoplasm frontal. MRI findings: A heterogeneous enhancing mass is seen centered in the left frontal lobe which measures approximately 6.8 x 4.4 cm. This is not significantly changed compared to prior outside MRI. There is again significant mass effect with effacement of sulci and herniation of the left frontal hemisphere across the midline. There is surrounding T1 hypodensity which likely represents vasogenic edema. Central areas of low T1 signal intensity likely represent necrosis.

GROSS EXAMINATION:

A. "Brain tissue (AF1)". Received fresh for frozen section is a 1.8 x 0.5 x 0.3 cm aggregate of soft brown-tan tissue is partially frozen as representative AF1 and the frozen section remnant is submitted in block A1. Additional representative sections submitted in block A2 and the remainder is retained in formalin.

B. "Brain tissue (BF1)". Received fresh for frozen section is a 4.3 x 3.8 x 1.9 cm aggregate of soft gray-tan tissue that was partially frozen as representative BF1 and the frozen section remnant is submitted in B1. Additional representative sections are submitted in blocks B2-5.

C. "Brain tissue-routine". Received fresh and placed in formalin is a 4.6 x 2.1 x 2.1 cm portion of scabrous gray-tan tissue with embedded blood clot. Representative sections blocks C1-3.

INTRA OPERATIVE CONSULTATION:

- A. "Brain tissue":AF1-glioma, probable oligodendroglioma.
B. "Brain tissue":BF1-high grade glioma, probable oligo (Dr.

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by an oligodendroglial neoplasm characterized by hypercellularity, minigemistocytes, mitotic figures, microvascular changes and necrosis.

DIAGNOSIS:

- A. "BRAIN TISSUE" (CRANIOTOMY):
ANAPLASTIC OLIGODENDROGLIOMA (WHO GRADE III).
- B. "BRAIN TISSUE" (CRANIOTOMY):
ANAPLASTIC OLIGODENDROGLIOMA (WHO GRADE III).
- C. "BRAIN TISSUE" (CRANIOTOMY):
ANAPLASTIC OLIGODENDROGLIOMA (WHO GRADE III).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ICD-O-3
Oligodendroglioma, grade III 94512
CNS
Site Brain, supratentorial C71.0
Brain, frontal lobe C71.1
7/5/14

[page 2 of 3]
ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

FISH INTERPRETATION SUMMARY:

CHROMOSOME 7 CENTROMERE - POLYSOMY (63% OF TUMOR CELLS EXHIBIT POLYSOMY)

EGFR - POLYSOMY (66% OF TUMOR CELLS EXHIBIT POLYSOMY)

CHROMOSOME 10 CENTROMERE - INTACT (NO LOSS)

PTEN - INTACT (NO LOSS)

1p36 - LOSS (82% OF TUMOR CELLS EXHIBIT A RATIO FOR 1p36/1q25 OF LESS THAN 1.0)

1p32 - LOSS (74% OF TUMOR CELLS EXHIBIT A RATIO FOR 1p32/1qtel OF LESS THAN 1.0)

19q13 - INTACT (NO LOSS)

9p21 - LOSS (35% OF TUMOR CELLS EXHIBIT LOSS)

CHROMOSOME 9 CENTROMERE - INTACT (NO LOSS)

19q IS INTACT INDICATING THAT THIS TUMOR MAY NOT RESPOND THERAPEUTICALLY LIKE THAT TYPICALLY ASSOCIATED WITH THE OLIGODENDROGLIOMA WITH A LOSS OF 1p AND 19q.

PTEN IMMUNOHISTOCHEMISTRY DEMONSTRATES A LOSS WHILE FISH INDICATES BOTH ALLELES TO BE INTACT. EPIGENETIC MECHANISMS SUCH AS METHYLATION CAN EXPLAIN THIS APPARENT DISCREPANCY.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ADDENDUM 2:

BRAIN TISSUE CONTAINING ANAPLASTIC OLIGODENDROGLIOMA (WHO GRADE III; [REDACTED] BLOCK B4).

LEUCOCYTE COMMON ANTIGEN (LCA): 15% OF POSITIVE CELLS.

PROLIFERATION INDEX INTERPRETATION: HIGH PROLIFERATION INDEX (15% OF TUMOR CELLS EXHIBIT STAINING).

MGMT - NEGATIVE (5% OF TUMOR CELLS)

EGFR wt - POSITIVE (2+ IN 80% OF TUMOR CELLS)

EGFR vIII - NEGATIVE (0% OF TUMOR CELLS)

PTEN - LOSS (2+ IN 5% OF TUMOR CELLS)

S6 - POSITIVE (2+ IN 30% OF TUMOR CELLS)

AKT - NEGATIVE (2+ IN 20% OF TUMOR CELLS)

MAPK - POSITIVE (2+ IN 40% OF TUMOR CELLS)

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

[page 3 of 3]
I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Performed by: Electronically signed: [REDACTED]
SURGICAL PATHOLOGY

Ordering MD:

Histology Discrepancy		✓
Concurrent/Synchronous Primary Neoplasm		✓

Source: NCI Genomic Data Commons file ce36e99f-dd83-4dfe-8299-5a31f4f2499f (TCGA-E1-A7YS.8C44E399-41A8-455E-86EA-CA05A8105540.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).